Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A736, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A736-01A (Primary Tumor).

ICD-O-3
Astrocytoma, grade III 940113
Site: Brain, supratentorial NOS
C71.0

Case #

Patient: Age (years): Gender:

Clinical diagnosis: Brain tumor

Date of procurement:

hw 8/15/13

Sample:

Gross description:

Received material presented by grayish-pink translucent pieces of right parietal lobe.

Microscopic description:

Received material is represented by brain tissue consistent with anaplastic astrocytoma.

Final diagnosis: Anaplastic astrocytoma: Grade III

Confidential

Criteria	hw 8/13/13	Yes	No
Case ID (circle):	QUAIFIED		DISQUALIFIED

Source: NCI Genomic Data Commons file 90b65409-8a4c-4b01-9163-1550f0db7b75 (TCGA-P5-A736.46EF7549-943C-45E2-98AA-8A75A518FE51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).